Gene-level copy-number profile of tumor specimen TCGA-55-8085-01A from TCGA case TCGA-55-8085, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.6 years (23,596 days).
Specimen TCGA-55-8085-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.edba9ef5-2f7e-4b82-ad5b-6fc8143bc903.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8085-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19be3f15-6bd0-4c90-9bed-bf4b8a57e027

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,165; copy number 2: 39,296; copy number 3: 7,787; copy number 4: 3,298; copy number 5: 213; copy number 6: 43; copy number 7: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8085-01A-11D-2237-01): tumor purity 0.56, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 267 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:128,405,269–128,564,679, 1 gene, copy number 6 (within-gene range 3–6): LINC00824.
- chr14:40,267,283–40,905,513, 2 genes, copy number 6 (within-gene range 3–6): AL049828.2, AL390800.1.
- chr14:42,259,731–44,567,467, 21 genes, copy number 5–7 (within-gene range 4–7): AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1.
- chr14:51,637,348–64,387,986, 243 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
